Somatic mutation profile of tumor specimen TCGA-G5-6641-01A (aliquot TCGA-G5-6641-01A-11D-1826-10) from TCGA case TCGA-G5-6641, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,486 days).
Specimen TCGA-G5-6641-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ed14700-d21e-45bc-8418-b9eca9ce40ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G5-6641-10A (Blood Derived Normal), aliquot TCGA-G5-6641-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74d435ba-e703-492c-ab5a-180a8ca6b806

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Frame Shift Del 1, RNA 1, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 42/78 reads (54%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.5762+1G>T p.X1921_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as rs869312756, COSV53726767, COSV99590061; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.6908dup p.E2304Gfs*69 | Frame Shift Ins (INS) | VAF 29/75 reads (39%) | catalogued as rs773570504; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTBL2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs747084615, COSV70661387; called by muse, mutect2, varscan2
- ADAMTS18 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147816593; called by muse, mutect2, varscan2
- ADSS2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63695355; called by muse, mutect2, varscan2
- AMY2B | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.606); catalogued as COSV63715657; called by muse, mutect2
- CATSPER1 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.156); catalogued as COSV56411339; called by muse, varscan2
- CDH18 | c.2015A>T p.D672V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56929726; called by muse, mutect2, varscan2
- CEACAM3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.441); catalogued as rs377521292, COSV55761247; called by muse, mutect2, varscan2
- CYP2D6 | c.697A>T p.I233F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV62244264; called by muse, mutect2, varscan2
- DHX36 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 23/162 reads (14%) | catalogued as rs746199451, COSV100273668; called by muse, mutect2, varscan2
- DMBX1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV63602159; called by muse, mutect2, varscan2
- DNAH11 | c.3922G>A p.V1308M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100179504; called by muse, mutect2, varscan2
- DPY19L3 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs748028225, COSV60477578; called by mutect2, varscan2
- EGR1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1389045967, COSV53519999; called by muse, mutect2, varscan2
- EHD1 | c.1266C>A p.F422L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57733419, COSV57735205; called by muse, mutect2, varscan2
- EHMT1 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs886613648, COSV71777807; called by muse, mutect2, varscan2
- FTHL17 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs771095024, COSV100784283; called by muse, mutect2, varscan2
- FXR1 | c.1150A>G p.S384G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV99976414; called by muse, mutect2, varscan2
- GATA2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as rs1345163538, COSV62006771, COSV62008146; ClinVar: uncertain significance; called by muse, mutect2
- GON4L | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs141714959; called by muse, mutect2, varscan2
- HRNR | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs201797889; called by mutect2, varscan2
- IL17REL | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs147243670, COSV58008385; called by muse, mutect2, varscan2
- IMPG1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64058829; called by muse, mutect2, varscan2
- ITGB2 | c.2341G>A p.A781T (on ENST00000302347; = p.A757T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1421408165, COSV56610791; called by muse, mutect2, varscan2
- KIF27 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99927046; called by muse, varscan2
- LIG4 | c.2001G>C p.M667I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV63597276; called by muse, mutect2, varscan2
- LILRA4 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); catalogued as rs1254725235, COSV52492023; called by muse, varscan2
- MARK4 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs756740251, COSV53463093; called by muse, mutect2
- MGAM | c.4348T>A p.L1450M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV72074883; called by muse, mutect2
- MRPS18B | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV52543046; called by muse, mutect2
- MYCT1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs759084346, COSV65891392, COSV65891469; called by muse, mutect2, varscan2
- NAA16 | c.1762T>A p.S588T | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV65128628; called by muse, mutect2, varscan2
- NELFB | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs150102832; called by muse, mutect2, varscan2
- NSMCE3 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54274319; called by muse, mutect2, varscan2
- OR2B11 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs145019591; called by muse, mutect2
- OR2T4 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV63544213; called by muse, mutect2, varscan2
- OR4A47 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.622); catalogued as rs760834608, COSV71445022; called by muse, mutect2, varscan2
- OXSM | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV55001862; called by muse, mutect2
- PGA5 | c.918C>T p.D306= | Splice Region (SNP) | VAF 13/87 reads (15%) | catalogued as rs202236720; called by muse, mutect2, varscan2
- PLAG1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs771690216, COSV100387903, COSV57609257; called by muse, mutect2, varscan2
- PNMA1 | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99678953; called by muse, mutect2, varscan2
- PRB2 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs768807460, COSV66983346; called by muse, mutect2, varscan2
- PREX1 | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV64252933; called by muse, mutect2, varscan2
- PTPRM | c.3884G>T p.C1295F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59864367; called by muse, mutect2, varscan2
- RET | c.2109G>C p.Q703H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV100393819; called by mutect2, varscan2
- RHEB | c.383T>A p.V128E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as COSV100062166; called by muse, mutect2, varscan2
- SLC16A4 | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.755); catalogued as COSV100872966; called by muse, mutect2
- SLC1A3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs199787096, COSV54314157; called by mutect2, varscan2
- SLC26A8 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs769836507, COSV62885120, COSV62886216; called by muse, mutect2, varscan2
- SLC52A3 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs145194879; called by muse, mutect2, varscan2
- SLC6A16 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV60028334; called by muse, mutect2, varscan2
- SNAPC4 | c.4099C>T p.R1367W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762483291, COSV53734133; called by muse, mutect2, varscan2
- SORBS2 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1354381349, COSV53003521; called by muse, mutect2, varscan2
- SORCS2 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1039521878, COSV61168940; called by muse, mutect2, varscan2
- TDP2 | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV57764748; called by muse, mutect2, varscan2
- TENM1 | c.3599T>G p.L1200* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100950267, COSV100951297; called by muse, mutect2
- TMF1 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV68374546; called by muse, mutect2, varscan2
- TPO | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs757274238, COSV100221386; called by muse, mutect2, varscan2
- TPTE2 | c.525A>T p.L175F (on ENST00000400230 / NM_199254.2; = p.L98F on NM_130785.3) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as COSV55022902; called by muse, mutect2, varscan2
- TSPAN11 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV53819158; called by muse, mutect2
- UGT2B10 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV99608413; called by muse, mutect2, varscan2
- ZIC4 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs375753545, COSV67172875; called by muse, mutect2, varscan2
- ZNF347 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs765677009, COSV61967447, COSV61969032; called by muse, mutect2, varscan2
- ZNF416 | c.1005_1010del p.F335_Q337delinsL | In Frame Del (DEL) | VAF 8/74 reads (11%) | catalogued as COSV52184827; called by mutect2, pindel, varscan2
- ADGRA3 | c.2233-1G>A p.X745_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- GDF10 | c.1300_1308dup p.I434_P436dup | In Frame Ins (INS) | VAF 10/21 reads (48%) | called by mutect2, varscan2
- OR4C13 | c.254_271del p.Y85_I90del | In Frame Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- AHI1 | c.384G>A p.K128= | Silent (SNP) | VAF 52/328 reads (16%) | catalogued as COSV55629428; called by muse, mutect2, varscan2
- ANKRD28 | c.2961A>G p.S987= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV101080717; called by muse, mutect2
- ARL14 | c.21A>G p.K7= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV57899971; called by muse, mutect2, varscan2
- BEST3 | c.1797C>T p.S599= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100437807; called by muse, mutect2
- CHAT | c.82A>C p.R28= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV60326870; called by muse, mutect2, varscan2
- CHST11 | c.468C>T p.H156= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs1408686961, COSV57988559; called by muse, mutect2, varscan2
- ERP44 | c.897C>T p.A299= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1325647795, COSV52432581; called by muse, mutect2, varscan2
- ETNK1 | c.459A>G p.A153= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as rs1209229220, COSV99860778; called by muse, mutect2, varscan2
- FLG | c.4365C>T p.H1455= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs142950612; called by muse, mutect2, varscan2
- FNDC1 | c.5013C>T p.H1671= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs763700928, COSV99796046; called by mutect2, varscan2
- MGA | c.2742T>G p.S914= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV54956215; called by muse, mutect2, varscan2
- NEFL | c.243C>T p.N81= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as COSV55337339; called by muse, mutect2, varscan2
- NLRP12 | c.888C>T p.F296= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as rs538564043, COSV60749158; called by muse, mutect2, varscan2
- OR2M4 | c.801G>A p.T267= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs757716230, COSV60708501; called by muse, mutect2, varscan2
- OR8H3 | c.516C>T p.N172= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV57909389; called by muse, mutect2, varscan2
- PARP12 | c.1521G>A p.S507= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs749786679, COSV54935061; called by muse, mutect2, varscan2
- PCDHA2 | c.1644C>T p.N548= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV65367787; called by muse, mutect2, varscan2
- PIGR | c.258C>T p.N86= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs776231853, COSV100732530; called by muse, mutect2, varscan2
- RABGGTA | c.1044C>T p.D348= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs756581262, COSV53770771; called by muse, mutect2, varscan2
- RADIL | c.2811A>G p.G937= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV68201620; called by muse, mutect2, varscan2
- ROBO1 | c.3408C>A p.I1136= | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as COSV71395591; called by muse, mutect2, varscan2
- SAMD9 | c.3849T>C p.N1283= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV66076047; called by muse, mutect2, varscan2
- SVEP1 | c.447G>A p.K149= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1466069907, COSV57038749; called by muse, mutect2, varscan2
- TGIF2LY | c.552G>A p.P184= | Silent (SNP) | VAF 66/90 reads (73%) | catalogued as rs747218743, COSV58291759; called by muse, mutect2, varscan2
- TMEM200C | c.276G>A p.A92= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs896916902, COSV67309624; called by muse, mutect2, varscan2
- ZNF610 | c.1125C>T p.N375= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs774200538, COSV58345203; called by muse, mutect2, varscan2
- ALOX12B | c.*1G>A | 3'UTR (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100047221; called by muse, mutect2, varscan2
- SSPOP | n.7774G>A | RNA (SNP) | VAF 9/25 reads (36%) | catalogued as rs747013219, COSV65131717; called by muse, mutect2, varscan2
